Somatic mutation profile of tumor specimen MMRF_2549_1_BM_CD138pos (aliquot MMRF_2549_1_BM_CD138pos_T1_KHS5U_K15160) from MMRF case MMRF_2549, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.8 years (23,652 days).
Specimen MMRF_2549_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd698dd5-b2bf-4710-a103-b07f0ebefa8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2549_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2549_1_PB_Whole_C3_KHS5U_K15159; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f457a1d-a0ad-46d2-bb01-18ea96530169

The open-access MAF lists 164 somatic variants for this specimen: 71 protein-altering or splice-affecting, 19 silent, 74 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, 3'UTR 38, Silent 19, Intron 15, 5'UTR 9, 5'Flank 5, 3'Flank 4, RNA 3, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADIPOR1 | c.1058A>G p.Y353C | Missense Mutation (SNP) | VAF 5/137 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1454766490, COSV61852487; called by muse, mutect2
- ARG2 | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs769482292; called by muse, mutect2, varscan2
- AUTS2 | c.2906C>T p.P969L | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1266794556; called by muse, mutect2
- C12orf50 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1257252181; called by muse, mutect2, varscan2
- CFAP65 | c.4106G>A p.R1369Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as rs564721573, COSV100445669; called by muse, mutect2, varscan2
- COL6A2 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs886044462, COSV100154474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CREB3L3 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1215881812; called by muse, mutect2
- CTNND1 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.818); catalogued as rs777009146; called by muse, mutect2, varscan2
- DENND6B | c.1513A>G p.M505V | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.15); catalogued as rs1210112970; called by muse, mutect2, varscan2
- ELFN1 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV70033740; called by muse, mutect2, varscan2
- EPN1 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 16/247 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99321824; called by muse, mutect2
- GPC5 | c.1717T>C p.*573Qext*48 | Nonstop Mutation (SNP) | VAF 16/304 reads (5%) | catalogued as rs1566451691; called by muse, mutect2
- GRSF1 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 89/175 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.213); catalogued as rs753538777; called by muse, mutect2, varscan2
- HMGCS2 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as COSV101024878; called by muse, mutect2
- IGHV2-70 | c.290A>G p.N97S | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs769646259; called by muse, varscan2
- IGHV5-51 | c.71T>A p.V24E | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as rs369364235; called by muse, mutect2
- IGSF9 | c.1520G>A p.S507N (on ENST00000368094 / NM_001135050.2; = p.S491N on NM_020789.4) | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs1239826713, COSV63639525; called by muse, mutect2
- KIF26B | c.4030T>C p.S1344P | Missense Mutation (SNP) | VAF 65/95 reads (68%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100832236; called by muse, mutect2, varscan2
- KIF5A | c.1816C>T p.R606W | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1348214633; called by muse, mutect2, varscan2
- KIZ | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55685570; called by muse, mutect2, varscan2
- LRRC72 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.925); catalogued as rs1474018594; called by muse, mutect2, varscan2
- MEGF8 | c.2485G>A p.V829M (on ENST00000251268 / NM_001271938.2; = p.V762M on NM_001410.3) | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.38); catalogued as rs530378456; called by muse, mutect2, varscan2
- MXD4 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs201554312, COSV61466231; called by muse, mutect2, varscan2
- MYH15 | c.2857C>T p.R953W | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs1317895575, CM1513509, COSV56316216; called by muse, mutect2
- PLCG2 | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1369745419; called by mutect2, varscan2
- RUSC2 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 93/331 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs200615669, COSV100770796; called by muse, mutect2, varscan2
- SRD5A2 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs914715976, COSV51873921; called by muse, mutect2
- SYBU | c.1963C>T p.R655C (on ENST00000276646 / NM_001099754.2; = p.R654C on NM_017786.6) | Missense Mutation (SNP) | VAF 124/223 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762750044, COSV99406338; called by muse, mutect2, varscan2
- TRPM1 | c.2373G>A p.T791= | Splice Region (SNP) | VAF 15/92 reads (16%) | catalogued as rs771354727, COSV56633764; called by muse, mutect2, varscan2
- ZNF239 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.993); catalogued as rs200194724, COSV60018706; called by muse, mutect2, varscan2
- ADGB | c.3029C>T p.T1010I | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP12 | c.2830G>T p.E944* | Nonsense Mutation (SNP) | VAF 60/255 reads (24%) | called by muse, mutect2, varscan2
- ATP6V0A4 | c.2429+2T>C p.X810_splice | Splice Site (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- BRWD3 | c.2325+2T>C p.X775_splice | Splice Site (SNP) | VAF 29/48 reads (60%) | called by muse, mutect2, varscan2
- CLCN4 | c.445T>G p.Y149D | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CLPTM1 | c.761T>C p.V254A | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- COX6B2 | c.104A>G p.N35S | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- CPQ | c.811A>G p.T271A | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- DST | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FAT4 | c.1741G>A p.V581I | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.679); called by muse, mutect2
- ITPRID2 | c.1860A>T p.E620D | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- KIF4A | c.1709A>G p.N570S | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRI1 | c.272C>G p.T91R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- LRP2 | c.12075A>T p.K4025N | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); called by muse, mutect2
- MARCHF5 | c.107G>T p.R36I | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MFAP5 | c.246A>C p.A82= | Splice Region (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- MMP20 | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MROH2A | c.2342T>G p.V781G | Missense Mutation (SNP) | VAF 25/308 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); called by muse, mutect2
- NASP | c.1292_1293del p.E431Vfs*2 | Frame Shift Del (DEL) | VAF 17/69 reads (25%) | called by pindel, varscan2
- NPAT | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- NUMBL | c.231del p.C78Afs*13 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- OR4K5 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 71/331 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- OTOG | c.1751T>C p.L584P | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OTUD6A | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH17 | c.1409C>G p.P470R | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEG3 | c.1278G>A p.M426I | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIWIL3 | c.217T>A p.S73T | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- PLXNA2 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPGR | c.1102C>G p.H368D | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- SLC22A7 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC7A14 | c.125C>T p.T42I | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SP140L | c.1676T>C p.L559P | Missense Mutation (SNP) | VAF 15/233 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- STAB2 | c.4489G>C p.V1497L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.017); called by muse, mutect2
- TACC2 | c.5750A>C p.H1917P | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBR1 | c.1761G>T p.E587D | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2
- TRAV29DV5 | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIP12 | c.2449G>T p.D817Y | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- TTN | c.27770C>A p.S9257Y (on ENST00000591111; = p.S8330Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/80 reads (25%) | PolyPhen possibly damaging (0.834); called by mutect2, varscan2
- UBQLN2 | c.171T>A p.F57L | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- VNN2 | c.97C>T p.H33Y | Missense Mutation (SNP) | VAF 155/470 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ZNF133 | c.1187C>A p.T396N (on ENST00000316358 / NM_001352454.2; = p.T395N on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ASPRV1 | c.162C>G p.A54= | Silent (SNP) | VAF 45/115 reads (39%) | called by muse, mutect2, varscan2
- BRPF1 | c.2727C>T p.G909= | Silent (SNP) | VAF 60/179 reads (34%) | called by muse, mutect2, varscan2
- CFAP61 | c.2589C>A p.I863= | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2
- CREBZF | c.825T>G p.T275= | Silent (SNP) | VAF 72/164 reads (44%) | called by muse, mutect2, varscan2
- DGKG | c.2058T>A p.G686= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as COSV99403181; called by muse, mutect2, varscan2
- DSG3 | c.2700T>A p.T900= | Silent (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- DUSP2 | c.573G>A p.L191= | Silent (SNP) | VAF 97/154 reads (63%) | called by muse, mutect2, varscan2
- EHMT2 | c.1869G>A p.L623= | Silent (SNP) | VAF 20/234 reads (9%) | catalogued as rs143349295; called by muse, mutect2
- FAM110B | c.228G>A p.K76= | Silent (SNP) | VAF 60/148 reads (41%) | called by muse, mutect2, varscan2
- FAM47C | c.204G>A p.T68= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV100792322; called by muse, mutect2, varscan2
- IFRD2 | c.84C>A p.L28= | Silent (SNP) | VAF 15/153 reads (10%) | called by muse, mutect2
- IL1R2 | c.510C>T p.Y170= | Silent (SNP) | VAF 46/166 reads (28%) | called by muse, mutect2, varscan2
- MAP1A | c.1512A>T p.T504= | Silent (SNP) | VAF 10/157 reads (6%) | called by muse, mutect2
- MEX3B | c.1059C>T p.P353= | Silent (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
- RABEPK | c.456A>C p.L152= | Silent (SNP) | VAF 31/379 reads (8%) | called by muse, mutect2
- S1PR3 | c.285C>T p.N95= | Silent (SNP) | VAF 79/254 reads (31%) | catalogued as rs1268496613; called by muse, mutect2, varscan2
- TRPV5 | c.2157T>C p.S719= | Silent (SNP) | VAF 104/328 reads (32%) | called by muse, varscan2
- ZNF497 | c.1326C>T p.F442= | Silent (SNP) | VAF 6/113 reads (5%) | called by muse, mutect2
- ZNF836 | c.1125T>C p.N375= | Silent (SNP) | VAF 86/234 reads (37%) | called by muse, mutect2, varscan2
- AGR2 | c.478+247C>T | Intron (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- ANAPC7 | c.777-458C>T | Intron (SNP) | VAF 17/26 reads (65%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.*1580dup | 3'UTR (INS) | VAF 18/58 reads (31%) | called by pindel, varscan2
- ASPN | c.*104T>C | 3'UTR (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- BEND4 | c.*5363C>T | 3'UTR (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- BMP6 | c.*1185_*1186del | 3'UTR (DEL) | VAF 22/60 reads (37%) | catalogued as rs548593250; called by mutect2, varscan2
- BROX | c.*234C>A | 3'UTR (SNP) | VAF 6/76 reads (8%) | catalogued as rs1009252243; called by muse, mutect2
- C1RL | c.*1822del | 3'UTR (DEL) | VAF 15/28 reads (54%) | catalogued as rs1308076290; called by mutect2, pindel, varscan2
- C1orf21 | c.*1398C>T | 3'UTR (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- CACNA2D3 | c.204+146G>A | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2
- CAND1 | c.*4007T>C | 3'UTR (SNP) | VAF 12/30 reads (40%) | called by muse, varscan2
- CIDEC | c.*140G>T | 3'UTR (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- CLIC2 | c.*103C>T | 3'UTR (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- COL4A4 | c.*2358_*2367del | 3'UTR (DEL) | VAF 40/74 reads (54%) | called by mutect2, pindel, varscan2
- CSAD | c.648-22C>A | Intron (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- CSDE1 | c.*1242T>A | 3'UTR (SNP) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- CSF1R | c.*476G>A | 3'UTR (SNP) | VAF 33/123 reads (27%) | called by muse, mutect2, varscan2
- DEFB118 | c.*699A>G | 3'UTR (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2
- DLX6 | c.437-133C>T | Intron (SNP) | VAF 11/189 reads (6%) | called by muse, mutect2
- DRD5 | c.-293C>T | 5'UTR (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- EDRF1 | chr10:125719682 C>G | 5'Flank (SNP) | VAF 13/158 reads (8%) | called by muse, mutect2
- EFCAB2 | c.*2644T>G | 3'UTR (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- EGR3 | c.154+443A>G | Intron (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
- ERMARD | c.*64A>G | 3'UTR (SNP) | VAF 44/168 reads (26%) | called by muse, mutect2, varscan2
- FAH | c.455+1087G>A | Intron (SNP) | VAF 6/147 reads (4%) | called by muse, mutect2
- FAM78A | c.*222G>A | 3'UTR (SNP) | VAF 7/157 reads (4%) | catalogued as rs923997281, COSV55991988; called by muse, mutect2
- FOXI2 | chr10:127736620 C>A | 5'Flank (SNP) | VAF 47/106 reads (44%) | called by muse, mutect2, varscan2
- FOXN4 | c.*903C>A | 3'UTR (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- GAPDH | c.29+165G>A | Intron (SNP) | VAF 21/46 reads (46%) | catalogued as rs977435564; called by muse, mutect2, varscan2
- HOATZ | c.453-222C>T | Intron (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- IGHV3-7 | c.-60T>C | 5'UTR (SNP) | VAF 45/45 reads (100%) | catalogued as rs554698139; called by muse, mutect2, varscan2
- INAVA | c.*251A>G | 3'UTR (SNP) | VAF 54/276 reads (20%) | called by muse, mutect2, varscan2
- KCNC1 | c.-905C>T | 5'UTR (SNP) | VAF 3/39 reads (8%) | catalogued as rs1271701162; called by muse, mutect2
- KLHL20 | c.597+83G>A | Intron (SNP) | VAF 71/119 reads (60%) | catalogued as rs777461940; called by muse, mutect2, varscan2
- LEO1 | c.*17A>C | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- LGALS9 | chr17:27630611 G>A | 5'Flank (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- LGR6 | chr1:202189295 G>A | 5'Flank (SNP) | VAF 10/142 reads (7%) | catalogued as rs1432712787; called by muse, mutect2
- LINC02312 | n.1839G>T | RNA (SNP) | VAF 15/100 reads (15%) | called by muse, mutect2, varscan2
- LMNTD1 | c.-138G>A | 5'UTR (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- LRP1B | c.*1634T>A | 3'UTR (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- LRRC58 | c.*4708T>A | 3'UTR (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- LY6G5C | c.345+1666C>T | Intron (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- MAGEC2 | c.*421T>A | 3'UTR (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- MAML2 | c.*1426A>G | 3'UTR (SNP) | VAF 27/57 reads (47%) | catalogued as rs180707168; called by muse, mutect2, varscan2
- NKPD1 | c.-68C>T | 5'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- NPTXR | c.*631C>A | 3'UTR (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2, varscan2
- OTUD3 | c.-10G>A | 5'UTR (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- PATJ | c.*1489G>C | 3'UTR (SNP) | VAF 36/63 reads (57%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+4166C>T | Intron (SNP) | VAF 52/167 reads (31%) | catalogued as COSV56506392; called by muse, mutect2, varscan2
- PHLDA3 | chr1:201465789 T>C | 3'Flank (SNP) | VAF 7/163 reads (4%) | called by muse, mutect2
- PLEKHG2 | c.-22-65C>T | Intron (SNP) | VAF 14/260 reads (5%) | catalogued as COSV99218377; called by muse, mutect2
- POU2F2 | chr19:42088491 del TC | 3'Flank (DEL) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- PPP1R9A | c.*4850dup | 3'UTR (INS) | VAF 39/148 reads (26%) | called by mutect2, pindel, varscan2
- PRKAA2 | c.*6200G>T | 3'UTR (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- PRRX1 | c.*2698G>A | 3'UTR (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- PSG10P | n.1321G>A | RNA (SNP) | VAF 11/292 reads (4%) | catalogued as rs1313876439; called by muse, mutect2
- RAPGEF1 | c.*8C>T | 3'UTR (SNP) | VAF 165/271 reads (61%) | catalogued as rs754708795, COSV64701490; called by muse, mutect2, varscan2
- RHOT1 | chr17:32141349 C>T | 5'Flank (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- RUBCN | c.*1951G>T | 3'UTR (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- SLCO6A1 | c.-84C>T | 5'UTR (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- SORCS2 | c.*1641C>T | 3'UTR (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2, varscan2
- SOX30 | c.*21G>C | 3'UTR (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- SPEM2 | c.-1C>T | 5'UTR (SNP) | VAF 4/80 reads (5%) | catalogued as COSV100080739; called by muse, mutect2
- TENT5D | c.*220T>G | 3'UTR (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- TMEM144 | c.*1039C>G | 3'UTR (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2
- TOR1B | c.*767del | 3'UTR (DEL) | VAF 4/39 reads (10%) | catalogued as rs1287033793; called by pindel, varscan2
- TP53INP2 | c.*659G>A | 3'UTR (SNP) | VAF 9/153 reads (6%) | catalogued as rs931170789; called by muse, mutect2
- TPRX2P | n.565T>A | RNA (SNP) | VAF 50/349 reads (14%) | called by muse, mutect2, varscan2
- TRAK1 | c.286+23819T>G | Intron (SNP) | VAF 29/111 reads (26%) | called by muse, mutect2, varscan2
- TRPV5 | c.*35T>C | 3'UTR (SNP) | VAF 76/270 reads (28%) | called by muse, varscan2
- USP16 | c.-21A>G | 5'UTR (SNP) | VAF 68/143 reads (48%) | called by muse, mutect2, varscan2
- ZFP36L1 | c.*6+329A>C | Intron (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- ZNF839 | chr14:102342583 T>G | 3'Flank (SNP) | VAF 42/81 reads (52%) | catalogued as rs1160298844; called by muse, mutect2, varscan2
- ZNFX1 | chr20:49243794 C>T | 3'Flank (SNP) | VAF 41/124 reads (33%) | called by muse, mutect2, varscan2
